Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A6ES, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A6ES-01A (Primary Tumor).

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge: Surgery and Laryngological Oncology Dept.

Physician in charge:

Clinical diagnosis (suspicion) Laryngeal carcinoma Histopathology result: squamous cell carcinoma T4a N1 MO

Date of admission:

Material:

1) Material: Larynx. Please examine the margins. Method of collection: Collection of specimens for laboratory examination

Histopathological diagnosis

Examination performed on:

Squamous cell carcinoma T4a N1 MO

Assistant:

Pathologist

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-O-3

Carcinoma, squamous cell NOS
8670/3

Site: Larynx NOS
C32.9

W 5/24/13

Criteria	No
Dis. mod. discrepancy	✓
HPOA Discrepancy	✓
Prior Maintenance History	
Case in Circle	

W 5/24/13

5/17/13

Source: NCI Genomic Data Commons file bf9a771c-29a7-4049-9142-3b19f2dfeaf7 (TCGA-D6-A6ES.C552063F-5D9C-4D44-A8CE-C4BAA29352AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).